Somatic mutation profile of tumor specimen MP2PRT-PAUCRD-TMP1-A (aliquot MP2PRT-PAUCRD-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUCRD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,298 days).
Specimen MP2PRT-PAUCRD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39a5b29f-3198-4e2e-95d9-4e5e7fbe7380.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUCRD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUCRD-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/169efc97-98d1-485b-8743-ab0b8819b800

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 5, Intron 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1775T>C p.V592A | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1057520025, COSV54051432, COSV54058572, COSV54074139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 22/292 reads (8%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- CCDC40 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 10/247 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53905165; called by muse, mutect2
- DENND2C | c.2746C>T p.R916W (on ENST00000393274 / NM_001256404.2; = p.R859W on NM_198459.4) | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763423714, COSV67920298; called by muse, mutect2, varscan2
- OPN5 | c.1070C>A p.S357Y | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs1481516723; called by mutect2, varscan2
- OR8B12 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 54/380 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as rs148702196; called by muse, mutect2, varscan2
- SLC7A2 | c.1226C>T p.A409V (on ENST00000494857 / NM_001370338.1; = p.A448V on NM_003046.6) | Missense Mutation (SNP) | VAF 38/336 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as rs763868224, COSV99134483; called by muse, mutect2, varscan2
- SPTB | c.1378G>A p.A460T | Missense Mutation (SNP) | VAF 55/421 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs377510670; called by muse, mutect2, varscan2
- ADGRG7 | c.914C>T p.T305I | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CREBBP | c.1654_1655insAT p.P552Hfs*11 | Frame Shift Ins (INS) | VAF 15/169 reads (9%) | called by mutect2, pindel, varscan2
- GLE1 | c.1167G>C p.W389C | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ITGB6 | c.2075C>A p.T692N | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- KDM4F | c.1300C>T p.R434* | Nonsense Mutation (SNP) | VAF 54/357 reads (15%) | called by muse, mutect2, varscan2
- LRRFIP2 | c.1222G>T p.E408* | Nonsense Mutation (SNP) | VAF 36/144 reads (25%) | called by muse, mutect2, varscan2
- OR4K15 | c.506T>G p.V169G (on ENST00000305051; = p.V145G on NM_001005486.1) | Missense Mutation (SNP) | VAF 70/473 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PDLIM5 | c.1760G>T p.C587F | Missense Mutation (SNP) | VAF 25/261 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PIEZO2 | c.1844C>T p.S615L | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- RMND1 | c.435G>C p.K145N | Missense Mutation (SNP) | VAF 57/405 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- SYNE1 | c.14254A>T p.M4752L (on ENST00000367255 / NM_182961.4; = p.M4681L on NM_033071.3) | Missense Mutation (SNP) | VAF 64/386 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- WWC2 | c.1547A>G p.Q516R | Missense Mutation (SNP) | VAF 44/379 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF462 | c.5593C>T p.H1865Y | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- C4orf54 | c.1266G>T p.L422= | Silent (SNP) | VAF 14/478 reads (3%) | called by muse, mutect2
- CCNB3 | c.2181G>A p.K727= | Silent (SNP) | VAF 50/340 reads (15%) | called by muse, mutect2, varscan2
- ROBO1 | c.3597C>T p.S1199= | Silent (SNP) | VAF 26/306 reads (8%) | catalogued as rs373039151; called by muse, mutect2
- SALL3 | c.2847C>T p.G949= | Silent (SNP) | VAF 116/684 reads (17%) | catalogued as rs1451294076, COSV73306685; called by muse, mutect2, varscan2
- SERPINA10 | c.282C>T p.H94= | Silent (SNP) | VAF 63/595 reads (11%) | catalogued as rs371570431; called by muse, mutect2, varscan2
- INPP4A | c.2801+4496A>C | Intron (SNP) | VAF 55/408 reads (13%) | called by muse, mutect2, varscan2
- SHISA6 | c.800-3822G>A | Intron (SNP) | VAF 34/285 reads (12%) | catalogued as rs111817876, COSV69396574; called by mutect2, varscan2
